Somatic mutation profile of tumor specimen 1105265 (aliquot 7316UP-1581-1105265) from CPTAC case C383391, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Temporal lobe; Tumor grade: G3.
Specimen 1105265: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e855041-4911-4e07-8339-5243e238fe68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105272 (Blood Derived Normal), aliquot 7316UP-1108-1105272; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cce155a7-8be3-4c64-8e21-995c32b36b0c

The open-access MAF lists 86 somatic variants for this specimen: 53 protein-altering or splice-affecting, 25 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 25, Intron 4, Frame Shift Del 3, Nonsense Mutation 2, 3'UTR 1, RNA 1, Frame Shift Ins 1, In Frame Del 1, Splice Region 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 140/743 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAIN1 | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.062); catalogued as rs745657091, COSV71420513; called by muse, mutect2, varscan2
- ARHGAP44 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs367607261; called by muse, mutect2, varscan2
- BMP10 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs144469983; called by muse, mutect2, varscan2
- CAMSAP3 | c.3101G>A p.R1034H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as rs888893073, COSV50331293; called by muse, mutect2, varscan2
- CDC42BPB | c.4593A>G p.G1531= | Splice Region (SNP) | VAF 16/162 reads (10%) | catalogued as rs768519250; called by muse, mutect2
- CHAT | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 101/204 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs779668516, COSV60334873; called by muse, mutect2, varscan2
- COL6A5 | c.2644C>T p.R882W | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs374168010; called by muse, mutect2, varscan2
- DDX60 | c.2360C>T p.T787M | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1489149518; called by muse, mutect2, varscan2
- FAT1 | c.7556G>A p.G2519E | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs550477464; called by muse, mutect2, varscan2
- FRMPD4 | c.1955C>T p.S652F | Missense Mutation (SNP) | VAF 71/102 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66223539; called by muse, mutect2, varscan2
- GPR152 | c.1313C>T p.T438I | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV56887835; called by muse, varscan2
- HRNR | c.2140A>C p.S714R | Missense Mutation (SNP) | VAF 53/645 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV64257890; called by muse, mutect2
- KRTAP4-6 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 145/573 reads (25%) | SIFT tolerated (0.13); catalogued as rs763253803, COSV61980902; called by muse, mutect2, varscan2
- MYOD1 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51456293; called by muse, mutect2, varscan2
- OBI1 | c.799A>G p.M267V | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56146941; called by muse, mutect2
- ORC1 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as rs148581880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNKD | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 60/231 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs756863425, COSV51231403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTH2R | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 79/252 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.05); catalogued as rs753279962, COSV55915312; called by muse, mutect2, varscan2
- RBFOX1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376377058; called by muse, mutect2, varscan2
- RELN | c.9904G>A p.A3302T | Missense Mutation (SNP) | VAF 178/682 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs776769644, COSV59040921; called by muse, mutect2, varscan2
- RELN | c.2260C>T p.R754W | Missense Mutation (SNP) | VAF 161/574 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs759711654, COSV59024775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC4A4 | c.1235A>G p.N412S (on ENST00000264485 / NM_001098484.3; = p.N368S on NM_003759.4) | Missense Mutation (SNP) | VAF 14/393 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs886059596; ClinVar: uncertain significance; called by muse, mutect2
- TENM3 | c.7523G>A p.R2508H | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1328986770; called by muse, mutect2
- TUBA3C | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.695); catalogued as rs923497577, COSV67139620; called by muse, mutect2, varscan2
- VAV2 | c.1351G>A p.E451K (on ENST00000371850 / NM_001134398.2; = p.E446K on NM_003371.4) | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.772); catalogued as rs755369467; called by muse, mutect2, varscan2
- XKR3 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 80/199 reads (40%) | catalogued as rs562118958; called by muse, mutect2, varscan2
- ZFP41 | c.273G>C p.E91D | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV58087841; called by muse, mutect2
- ARMC3 | c.1961G>A p.G654E | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.122); called by muse, mutect2
- CD96 | c.1480A>G p.T494A (on ENST00000283285 / NM_198196.3; = p.T478A on NM_005816.5) | Missense Mutation (SNP) | VAF 140/390 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- CLEC4G | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CREBBP | c.3197G>A p.S1066N | Missense Mutation (SNP) | VAF 109/308 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRTC2 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 192/550 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.067); called by mutect2, varscan2
- CRYBG1 | c.3650C>A p.P1217Q | Missense Mutation (SNP) | VAF 74/251 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- DLC1 | c.776A>T p.D259V | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- EHMT1 | c.2812C>A p.H938N | Missense Mutation (SNP) | VAF 46/537 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FASTKD5 | c.144C>G p.S48R | Missense Mutation (SNP) | VAF 31/348 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2
- GLI1 | c.707A>G p.D236G | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.132); called by muse, mutect2
- GOLGA6A | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 44/1192 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2
- GOLGA7 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- LPAR4 | c.654A>G p.I218M | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- MAGEE1 | c.811T>G p.S271A | Missense Mutation (SNP) | VAF 16/271 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- MED12 | c.2481del p.D828Ifs*70 | Frame Shift Del (DEL) | VAF 30/169 reads (18%) | called by mutect2, pindel, varscan2
- MYH13 | c.2028T>A p.C676* | Nonsense Mutation (SNP) | VAF 50/171 reads (29%) | called by muse, mutect2, varscan2
- NOBOX | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 97/328 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RAB33A | c.420del p.P142Hfs*2 | Frame Shift Del (DEL) | VAF 25/165 reads (15%) | called by pindel, varscan2
- SCAF1 | c.1244_1256del p.R415Lfs*45 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by pindel, varscan2*
- SLC16A12 | c.268_279del p.I90_I93del | In Frame Del (DEL) | VAF 26/249 reads (10%) | called by mutect2, pindel
- THADA | c.2371C>A p.L791I | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TMEM132C | c.2708A>G p.K903R | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TPR | c.4719G>C p.Q1573H | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); called by muse, varscan2
- TRIO | c.8963G>T p.G2988V | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YTHDF3 | c.98dup p.D33Efs*2 | Frame Shift Ins (INS) | VAF 33/178 reads (19%) | called by mutect2, pindel, varscan2
- ADAM29 | c.612C>T p.V204= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as rs114696296, COSV63668865; called by muse, mutect2, varscan2
- ARID1A | c.6057C>T p.H2019= | Silent (SNP) | VAF 89/273 reads (33%) | called by muse, mutect2, varscan2
- ARPC4 | c.114G>A p.V38= | Silent (SNP) | VAF 41/122 reads (34%) | catalogued as rs1482592313; called by muse, mutect2, varscan2
- CHRM2 | c.117C>T p.I39= | Silent (SNP) | VAF 97/413 reads (23%) | catalogued as rs755854009, COSV57773475; called by muse, mutect2, varscan2
- CLSTN2 | c.2004C>T p.F668= | Silent (SNP) | VAF 82/260 reads (32%) | catalogued as rs778778245, COSV71720462; called by muse, mutect2, varscan2
- CYP4A11 | c.180C>T p.F60= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as rs763129685, COSV60222221; called by muse, mutect2, varscan2
- DLC1 | c.2967G>T p.G989= (on ENST00000276297 / NM_001348081.2; = p.G552= on NM_006094.5) | Silent (SNP) | VAF 50/140 reads (36%) | catalogued as rs1563589459; called by muse, varscan2
- DPYSL2 | c.645G>T p.L215= | Silent (SNP) | VAF 90/264 reads (34%) | called by muse, mutect2, varscan2
- MYH7 | c.4740C>T p.D1580= | Silent (SNP) | VAF 96/242 reads (40%) | catalogued as rs201469051, COSV62516883; called by muse, mutect2, varscan2
- NDRG4 | c.654G>A p.T218= (on ENST00000570248 / NM_001378344.1; = p.T250= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 59/162 reads (36%) | catalogued as rs781381338, COSV99262394; called by muse, mutect2, varscan2
- OR2AK2 | c.99C>G p.T33= | Silent (SNP) | VAF 28/102 reads (27%) | catalogued as COSV63554593; called by muse, mutect2, varscan2
- OR5AU1 | c.267G>A p.R89= | Silent (SNP) | VAF 124/363 reads (34%) | catalogued as rs779575360; called by muse, mutect2, varscan2
- P2RY4 | c.486C>T p.V162= | Silent (SNP) | VAF 27/128 reads (21%) | catalogued as rs374818208; called by muse, mutect2, varscan2
- PRDM16 | c.2667G>A p.P889= | Silent (SNP) | VAF 37/132 reads (28%) | catalogued as rs774537766; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCMH1 | c.6G>C p.L2= | Silent (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- SH2B1 | c.27C>T p.D9= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs772157677; called by muse, mutect2
- SLC30A3 | c.933G>A p.S311= | Silent (SNP) | VAF 67/287 reads (23%) | catalogued as rs538009364, COSV99273777, COSV99273918; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC7A14 | c.726G>A p.A242= | Silent (SNP) | VAF 89/255 reads (35%) | catalogued as rs752901596, COSV51580118; called by muse, mutect2, varscan2
- TANC1 | c.600C>T p.S200= | Silent (SNP) | VAF 102/331 reads (31%) | catalogued as rs1362556739; called by muse, mutect2, varscan2
- TOP2A | c.927G>A p.Q309= | Silent (SNP) | VAF 32/100 reads (32%) | catalogued as rs1403734143; called by muse, mutect2, varscan2
- TTC6 | c.2518C>A p.R840= | Silent (SNP) | VAF 45/243 reads (19%) | called by muse, mutect2, varscan2
- UNC13C | c.4164C>A p.V1388= | Silent (SNP) | VAF 55/196 reads (28%) | called by muse, mutect2, varscan2
- USH2A | c.6579C>T p.I2193= | Silent (SNP) | VAF 58/196 reads (30%) | catalogued as rs765566223; called by muse, mutect2, varscan2
- WDPCP | c.1608C>G p.L536= | Silent (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- ZAN | c.4158C>T p.C1386= | Silent (SNP) | VAF 67/252 reads (27%) | catalogued as rs376999914; called by muse, mutect2, varscan2
- DUX4L8 | n.706C>T | RNA (SNP) | VAF 71/1074 reads (7%) | catalogued as rs782032535; called by muse, mutect2
- GABBR1 | c.476-60G>T | Intron (SNP) | VAF 113/350 reads (32%) | catalogued as rs1347490372; called by muse, mutect2, varscan2
- LILRA5 | c.-44T>A | 5'UTR (SNP) | VAF 64/148 reads (43%) | catalogued as rs1380637405; called by muse, mutect2, varscan2
- MIER1 | c.*1496C>G | 3'UTR (SNP) | VAF 8/193 reads (4%) | called by muse, mutect2
- RNF130 | c.443-2050dup | Intron (INS) | VAF 5/46 reads (11%) | called by mutect2, pindel, varscan2
- SPEF2 | c.4448-4059C>T | Intron (SNP) | VAF 25/358 reads (7%) | catalogued as rs1385594622; called by muse, mutect2
- TMPRSS11F | c.1015+2142G>A | Intron (SNP) | VAF 35/296 reads (12%) | called by muse, mutect2, varscan2
- XIAP | chrX:123860208 G>A | 5'Flank (SNP) | VAF 55/294 reads (19%) | called by muse, mutect2, varscan2
